Somatic mutation profile of tumor specimen 0DJVPP from CCDI case PBBXJA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.0 years (5,494 days).
Specimen 0DJVPP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70c07234-4135-4b6b-acd2-317b88286e11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJVPA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2190d638-851a-4ea2-b27c-166d78491bfa

The open-access MAF lists 10 somatic variants for this specimen: 3 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 3, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMO | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 447/987 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs879255280, CM166287, COSV50824425; ClinVar: pathogenic; called by muse, varscan2
- THRB | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 232/714 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as rs121918706, CM981920, COSV54979906; ClinVar: pathogenic; called by muse, varscan2
- ANKMY1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 124/436 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs201252509, COSV56036648; called by muse, varscan2
- ATP10A | c.3534C>T p.A1178= | Silent (SNP) | VAF 340/708 reads (48%) | catalogued as rs759084161; called by muse, varscan2
- CELF5 | c.576C>T p.H192= | Silent (SNP) | VAF 162/589 reads (28%) | catalogued as rs1314852096; called by muse, varscan2
- COL6A3 | c.8220C>T p.V2740= | Silent (SNP) | VAF 191/686 reads (28%) | catalogued as COSV55113789; called by muse, varscan2
- FUCA2 | c.570C>T p.L190= | Silent (SNP) | VAF 301/612 reads (49%) | called by muse, varscan2
- IQGAP2 | c.726G>A p.A242= | Silent (SNP) | VAF 400/896 reads (45%) | catalogued as rs774632080, COSV99166621, COSV99167389; called by muse, varscan2
- NOG | c.*8G>A | 3'UTR (SNP) | VAF 136/266 reads (51%) | catalogued as rs532812087; called by muse, varscan2
- PROCA1 | c.175+92_175+96del | Intron (DEL) | VAF 27/55 reads (49%) | called by pindel, varscan2
